Somatic mutation profile of tumor specimen TARGET-20-PARLVL-04A (aliquot TARGET-20-PARLVL-04A-01D) from TARGET case TARGET-20-PARLVL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (963 days).
Specimen TARGET-20-PARLVL-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb6490c0-f8df-4d6b-a515-78a4a7a48159.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLVL-14A (Bone Marrow Normal), aliquot TARGET-20-PARLVL-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb3b987e-5dcc-49e1-a1df-74be0c68fc77

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 46/142 reads (32%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- WT1 | c.708del p.S238Rfs*53 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as COSV60070198; called by mutect2, pindel, varscan2
- WT1 | c.1304-15_1304-13del | Intron (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
